TCGA case TCGA-HZ-8317 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a2fd0991-cfbd-4162-8ca9-2ed096f54a14

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 378 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,214 days); Year of diagnosis: 2012; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 378 days (1.0 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 13; Tumor largest dimension diameter: 3.1 cm.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 105 days; Days to treatment end: 116 days; Treatment dose: 3,000 cGy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 137 days; Days to treatment end: 186 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.

Follow-up (2 entries)
- Days to follow up: 16 days; Disease response: With Tumor.
- Days to follow up: 378 days (1.0 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HZ-8317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-HZ-8317-01A-01-TS1: Section location: Top; Percent tumor cells: 32; Percent tumor nuclei: 10; Percent normal cells: 26; Percent necrosis: 0; Percent stromal cells: 42; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-HZ-8317-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HZ-8317-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: Fine Needle Aspiration Biopsy; Lymph nodes examined: Yes; Tumor status: With tumor; Alcohol history documented: No; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Cause of death: Pancreatic Cancer; New tumor event diagnosis indicator: No.
- Drug treatment: Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 378 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 378 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 378 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HZ-8317-01A-11D-2392-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
